Gene-level copy-number profile of tumor specimen MP2PRT-PARNXI-TMP1-A from MP2PRT case MP2PRT-PARNXI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,497 days).
Specimen MP2PRT-PARNXI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 80a4a0d0-32d2-43ec-8697-24ef6ea2ff1c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARNXI-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/c1bbfbff-f345-4e4e-83fc-e40365f4b67b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 129; copy number 1: 10; copy number 2: 19,269; copy number 3: 4,013; copy number 4: 27,604; copy number 5: 1,846; copy number 6: 5,391; copy number 7: 133.

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,221,113–87,459,044, 7 genes (within-gene range 0–1): CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943.
- chr2:87,477,495–87,478,034, 1 gene (within-gene range 0–1): AC133644.1.
- chr2:89,078,010–89,085,787, 2 genes (within-gene range 0–2): IGKV2-14, IGKV3-15.
- chr2:89,159,751–89,234,912, 10 genes (within-gene range 0–2): IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr2:89,947,512–89,990,221, 5 genes: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:90,114,838–90,315,836, 12 genes: IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118.
- chr7:38,256,337–38,311,808, 9 genes (within-gene range 0–4): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr9:10,777,357–10,777,525, 1 gene: AL161788.1.
- chr9:37,046,835–37,358,149, 10 genes (within-gene range 0–2): AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P.
- chr9:64,486,164–64,836,341, 10 genes: CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1.
- chr14:22,422,371–22,533,560, 61 genes (within-gene range 0–3) (broad region; genes not listed).
- chr16:85,676,198–85,690,073, 1 gene (within-gene range 0–2): GINS2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
